Surgical pathology report (de-identified scan), TCGA case TCGA-BK-A13C, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-BK-A13C-01A (Primary Tumor).

[page 1 of 3]
ICD-0-3
Adenocarcinoma, Endometrial, NOS
8380/3 for 11/14/10
Site: Endometrium
C54.1

SPECIMEN

- A. Uterus, cervix, bilateral tubes and ovaries
- B. Right pelvic lymph node
- C. Left pelvic lymph node
- D. Periaortic lymph node

CLINICAL NOTES

PRE-OP DIAGNOSIS: Endometrial cancer.

GROSS DESCRIPTION

A. Received is a container labeled with the patient's name

medical record number and uterus, cervix, bilateral tubes and ovaries. The specimen consists of uterus with attached ovaries and fallopian tubes. The uterus measures 10.5 cm the cervical tip to the fundus, 7.5 cm in breath and 5.5 cm in width. The uterus is bivalved and on sectioning there is a tan cerebriform firm tumor involving both anterior and posterior in the myometrial wall. The depth of invasion appears to be less than 50% of the myometrial wall. The lower uterine segment and endocervix are involved by tumor. The endocervical mucosa is tan smooth and glistening. The right and left ovaries average 1.5 x 1.5 x 1 cm. Accompany fallopian tubes average depth and centimeters in length and 0.5 cm in diameter. Representative sections after fixation.

6 B. Received fresh labeled "right pelvic lymph node" is a

x 4.8 x 1.8 cm aggregate of soft, lobulated, golden yellow adipose tissue. A few soft to slightly rubbery tan-pink-gold tissues in keeping with lymph nodes measuring up to 3 cm in greatest dimension are recovered. The lymphoid tissues are entirely submitted in five blocks as labeled. RS-5.

BLOCK SUMMARY: 1 - Five whole lymph nodes, 2-5 - one bisected lymph node per cassette.

GROSS DESCRIPTION

C. Received fresh labeled "left pelvic lymph node" is a 5 x 5 x 2.8 cm aggregate of soft, lobulated, golden yellow adipose tissue. Several soft to slightly rubbery tan-pink-gold tissues in keeping with lymph nodes measuring up to 2.5 cm in greatest dimension are recovered. The lymphoid tissues are entirely submitted in nine blocks as labeled. RS-9.

BLOCK SUMMARY: 1 and 2 - Three whole lymph nodes per cassette, 3-5 - one bisected lymph node per cassette, 6 and 7; 8 and 9 - one bisected node per pair of cassettes (one-half node per cassette - two nodes in toto represented).

[page 2 of 3]
x D. Received fresh labeled "periaortic lymph node" is a 4

3.5 x 1.5 cm aggregate of soft, lobulated, golden yellow adipose tissue. A few soft to slightly rubbery tan-pink-gold tissues in keeping with lymph nodes measuring up to 3 cm in greatest dimension are recovered. The lymphoid tissues are entirely submitted in four blocks as labeled. RS-4.

BLOCK SUMMARY: 1 - Five whole lymph node, 2-4 - one bisected lymph node per cassette.

MICROSCOPIC DESCRIPTION

A. The following template applies to the hysterectomy.

Histologic type: Endometrioid adenocarcinoma

Histologic grade: 2

Myometrial invasion:

0.4 cm depth of invasion

2.4 cm depth of myometrial thickness

17% of myometrial wall

MICROSCOPIC DESCRIPTION

Cervix: Not involved

Primary tumor: TNM 1b (FIGO): IB

Margins of resection: Not involved

Vascular invasion: Not identified

Regional lymph nodes (pN): Negative as described below pN0

Distant metastasis (pM): Could not be evaluated by this specimen (pMX)

Other findings: There is extensive adenomyosis within the myometrium. The ovaries and fallopian tubes are uninvolved by carcinoma.

of B. The right pelvic lymph nodes demonstrate no evidence of metastasis in 14 lymph nodes.

C. The left pelvic lymph nodes demonstrate no evidence of metastasis in 11 lymph nodes.

D. The periaortic lymph nodes demonstrate no evidence of metastasis in 5 lymph nodes.

4, 4x3

DIAGNOSIS

[page 3 of 3]
A. Uterus, cervix, resection:

No pathologic diagnosis.

Uterus, endomyometrium, hysterectomy:

Endometrioid adenocarcinoma, grade 2, depth of invasion 17%
through myometrial wall.

Ovaries, right and left, resection:

No pathologic diagnosis.

Fallopian tubes, right and left, resection:

No pathologic diagnosis.

B. Right pelvic lymph nodes, resection: No evidence of
metastasis to 14 lymph nodes (0/14).

C. Pelvic lymph nodes, resection: No evidence of
metastasis

DIAGNOSIS

to 11 lymph nodes (0/11).

D. Periaortic lymph nodes, resection: No evidence of metastasis
to

5 lymph nodes (0/5).

(Electronic Signature)

--- End Of Report ---

Source: NCI Genomic Data Commons file d4bdcd9d-3715-4479-bb48-b4b82bc22ba1 (TCGA-BK-A13C.2043D579-6785-4775-8A28-CDE3F1400BA2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).